MMRF case MMRF_2469 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/61872186-77a2-44bc-a058-930d381491df

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.0 years (19,362 days); ISS stage: III; Days to last known disease status: 736 days (2.0 years); Days to last follow up: 736 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 235 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 235 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 396 days (1.1 years); Days to treatment end: 396 days (1.1 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 397 days (1.1 years); Days to treatment end: 397 days (1.1 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: First line of therapy; Days to treatment start: 401 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 95 mg/dL; Immunoglobulin G 1.76 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 7.79 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.93 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 6.16 mmol/L; C-Reactive Protein 2.64 mg/dL.
- Day 71: Hemoglobin 5.77 mmol/L; Leukocytes 5 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 5.8 g/dL; Glucose 6.38 mmol/L.
- Day 233 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.039 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.2 mg/dL; Immunoglobulin G 1.32 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.73 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.53 mmol/L; Albumin 49 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 352: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.039 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.53 mg/dL; Immunoglobulin G 1.31 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.48 mmol/L; Albumin 47 g/L; Total Protein 6.3 g/dL; Glucose 8.36 mmol/L.
- Day 463 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.052 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.141 mg/dL; Immunoglobulin G 2.82 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.49 µg/mL; Hemoglobin 8.62 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 4.79 mmol/L.
- Day 542 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.109 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.456 mg/dL; Immunoglobulin G 2.33 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 6.38 mmol/L.
- Day 624 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.095 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.491 mg/dL; Immunoglobulin G 2.97 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 7.54 mmol/L.
- Day 736 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.949 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.594 mg/dL; Immunoglobulin G 3.74 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.9 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day -3: Weight: 103 kg; Height: 186 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2469_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2469_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
